Somatic mutation profile of tumor specimen TCGA-AG-A02X-01A (aliquot TCGA-AG-A02X-01A-01W-A00E-09) from TCGA case TCGA-AG-A02X, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.8 years (28,399 days).
Specimen TCGA-AG-A02X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74f2207c-4ba5-4819-a9fb-83b56466a32f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A02X-10A (Blood Derived Normal), aliquot TCGA-AG-A02X-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/442c8945-c46c-491a-8069-e2b510221c0a

The open-access MAF lists 138 somatic variants for this specimen: 100 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 36, Nonsense Mutation 13, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908212, CM960238, COSV64189612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 78/114 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 52/65 reads (80%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- AASS | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 21/863 reads (2%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100741914; called by muse, mutect2
- ACSM4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758311071, COSV68067600; called by muse, mutect2, varscan2
- ADGRG6 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as COSV51590986; called by muse, mutect2, varscan2
- AGMAT | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs199886325, COSV65435821; called by muse, mutect2, varscan2
- AHNAK | c.3463G>A p.V1155I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749813716, COSV57211895; called by muse, mutect2, varscan2
- AL592490.1 | c.1450A>G p.N484D | Missense Mutation (SNP) | VAF 121/201 reads (60%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV69425989; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 152/174 reads (87%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- ARL2BP | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | catalogued as COSV54656024, COSV54656784; called by muse, mutect2, varscan2
- ATG2B | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV55890183; called by muse, mutect2, varscan2
- BCAS2 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV65767402; called by muse, mutect2, varscan2
- BICD1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55678309; called by muse, mutect2, varscan2
- BICRAL | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV58405072; called by muse, mutect2, varscan2
- CAB39L | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV61714687; called by muse, mutect2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2, varscan2
- CDH16 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs779923317, COSV55334818; called by muse, mutect2, varscan2
- CDH22 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749043438, COSV64836992; called by muse, mutect2, varscan2
- CDH9 | c.1018C>A p.Q340K | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs796451473; called by muse, mutect2, varscan2
- CNTN4 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV61874810; called by muse, mutect2
- CPEB2 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.366); catalogued as rs781736943, COSV52592988; called by muse, mutect2
- CRACR2A | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 90/144 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52910682; called by muse, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 94/146 reads (64%) | catalogued as rs1385226543; called by mutect2, pindel, varscan2
- CYP4F22 | c.1341C>A p.Y447* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV54108101; called by muse, mutect2, varscan2
- DARS1 | c.1296A>G p.I432M | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51537873; called by muse, mutect2
- DAW1 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs756173701, COSV59364997; called by muse, mutect2, varscan2
- DGKI | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 92/168 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs568336252, COSV55947529; called by muse, varscan2
- DMKN | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as rs371442207, COSV60086857; called by muse, mutect2, varscan2
- DNAH2 | c.4834G>A p.D1612N | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs758120414, COSV66718920; called by muse, mutect2, varscan2
- EEA1 | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 33/330 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as COSV59287977; called by muse, mutect2
- EML1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs763147507, COSV51744418; called by muse, mutect2, varscan2
- EPHA5 | c.3056T>A p.I1019N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56642480; called by muse, mutect2, varscan2
- ESRRG | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV63159084; called by muse, mutect2, varscan2
- FAM133A | c.193dup p.M65Nfs*3 | Frame Shift Ins (INS) | VAF 74/113 reads (65%) | catalogued as rs760026337; called by mutect2, pindel, varscan2
- FCAR | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 47/92 reads (51%) | catalogued as rs766003893, COSV62028348, COSV62029418; called by muse, mutect2, varscan2
- FNDC1 | c.5366G>A p.R1789H | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796280954, COSV51948836; called by muse, mutect2
- FOXF2 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs910289542, COSV52525650; called by muse, mutect2, varscan2
- FSHR | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766731004, COSV100436649, COSV100437020, COSV58622557; called by muse, mutect2, varscan2
- HIPK2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.103); catalogued as COSV61227227; called by muse, mutect2, varscan2
- HMCN1 | c.12290C>T p.T4097M | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs370916387; called by muse, mutect2
- HNF4A | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as rs952494962, COSV57382348; called by muse, mutect2, varscan2
- IHO1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV56507453; called by muse, mutect2, varscan2
- IQCH | c.1775A>G p.D592G | Missense Mutation (SNP) | VAF 145/162 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV60052062; called by muse, mutect2, varscan2
- IQCK | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 103/168 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766973246, COSV57522152; called by muse, mutect2, varscan2
- KAT6B | c.2340A>C p.E780D | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54745960; called by muse, mutect2, varscan2
- KCNH7 | c.2665A>T p.K889* | Nonsense Mutation (SNP) | VAF 70/195 reads (36%) | catalogued as COSV59794959; called by muse, mutect2, varscan2
- KIAA1217 | c.1211T>G p.M404R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56815872; called by muse, mutect2
- LAMA3 | c.6094G>A p.E2032K (on ENST00000313654 / NM_198129.4; = p.E423K on NM_000227.6) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373464847; called by muse, mutect2, varscan2
- LONP2 | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 239/387 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53522131; called by muse, mutect2, varscan2
- LRFN5 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs553209511, COSV53242167, COSV53256587; called by muse, mutect2, varscan2
- LRP8 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs147119774; called by muse, mutect2
- LRRC43 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV60289657, COSV60290265; called by muse, mutect2, varscan2
- LTV1 | c.767T>A p.L256Q | Missense Mutation (SNP) | VAF 116/208 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62536377; called by muse, mutect2, varscan2
- MAGEH1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.024); catalogued as rs746007934, COSV61678788; called by muse, mutect2, varscan2
- MMP20 | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52775221; called by muse, mutect2, varscan2
- MYH11 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1220795088, COSV55551346; called by muse, mutect2
- NLRP8 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs187510597, COSV52586505; called by muse, mutect2, varscan2
- NUP205 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV53658254; called by muse, mutect2, varscan2
- OPCML | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747062268, COSV59419891; called by muse, varscan2
- OR8K3 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV57131387; called by muse, mutect2, varscan2
- PCBP2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV63728530; called by muse, mutect2, varscan2
- PCDHGA9 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV53937077; called by muse, mutect2, varscan2
- PPP1R15A | c.872C>A p.S291* | Nonsense Mutation (SNP) | VAF 17/184 reads (9%) | catalogued as COSV52338822; called by muse, mutect2, varscan2
- PUM1 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs779524509, COSV57084551; called by muse, mutect2, varscan2
- QRFPR | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV57676645; called by muse, mutect2, varscan2
- RAB40AL | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1410775082, COSV54434293; called by muse, mutect2, varscan2
- RPS3 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53704619; called by muse, mutect2, varscan2
- SCN3A | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 78/99 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs755167692, COSV51805904; called by muse, mutect2, varscan2
- SERPINA7 | c.1005T>A p.F335L | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.516); catalogued as COSV59665630; called by muse, mutect2, varscan2
- SIGLEC9 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs755507123, COSV51584041; called by muse, mutect2, varscan2
- SLC1A3 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 84/343 reads (24%) | catalogued as COSV54316119; called by muse, mutect2, varscan2
- SLC2A14 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61586399, COSV61586497; called by muse, mutect2, varscan2
- SLC4A4 | c.3154A>G p.M1052V (on ENST00000264485 / NM_001098484.3; = p.M1008V on NM_003759.4) | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52622886; called by muse, mutect2, varscan2
- SMAD4 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 57/75 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685194; called by muse, mutect2, varscan2
- SNX13 | c.1732T>C p.Y578H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV68064804; called by muse, mutect2, varscan2
- SPATA22 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205492213, COSV52151565, COSV52153888; called by muse, mutect2, varscan2
- SRRT | c.2137T>G p.W713G | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53817165; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | PolyPhen benign (0.019); catalogued as rs745998079, COSV59564668; called by muse, mutect2, varscan2
- SYTL3 | c.1034+1G>A p.X345_splice (on ENST00000611299 / NM_001242394.1; = p.X277_splice on NM_001009991.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/91 reads (24%) | catalogued as rs191050527, COSV99791949; called by muse, mutect2, varscan2
- TACR3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); catalogued as COSV59200856; called by muse, mutect2, varscan2
- TMEM63B | c.857C>A p.A286E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV52478446; called by muse, mutect2, varscan2
- TRAF3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1159452075, COSV61025030; called by muse, mutect2, varscan2
- TSEN15 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV62294261; called by muse, mutect2, varscan2
- TTN | c.90023G>A p.W30008* (on ENST00000591111; = p.W22584* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/224 reads (17%) | catalogued as COSV60016347; called by muse, mutect2
- WDFY2 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs138993465; called by muse, mutect2, varscan2
- ZNF335 | c.1264A>G p.N422D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1291333701, COSV59817477; called by muse, mutect2, varscan2
- ZNF492 | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 88/483 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV71761909; called by muse, mutect2, varscan2
- ZNF98 | c.1156G>C p.A386P | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63336127; called by muse, mutect2, varscan2
- ZSCAN25 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.616); catalogued as rs761704567, COSV53552866; called by muse, mutect2, varscan2
- DSC2 | c.2489C>T p.T830I | Missense Mutation (SNP) | VAF 129/152 reads (85%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MKI67 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- OR51M1 | c.685_691del p.S229Dfs*7 | Frame Shift Del (DEL) | VAF 99/268 reads (37%) | called by mutect2, pindel, varscan2
- PPEF2 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 18/382 reads (5%) | called by muse, mutect2
- SPTBN2 | c.4460C>A p.S1487Y | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMED10 | c.617_619del p.F206del | In Frame Del (DEL) | VAF 55/107 reads (51%) | called by pindel, varscan2*
- TRIM24 | c.3025dup p.R1009Kfs*10 (on ENST00000343526 / NM_015905.3; = p.R975Kfs*10 on NM_003852.4) | Frame Shift Ins (INS) | VAF 56/212 reads (26%) | called by mutect2, varscan2
- TRRAP | c.2891G>A p.W964* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.75032A>G p.N25011S (on ENST00000591111; = p.N17587S on NM_003319.4) | Missense Mutation (SNP) | VAF 12/275 reads (4%) | PolyPhen benign (0.288); called by muse, mutect2
- ZNF33B | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACOT7 | c.478C>T p.L160= (on ENST00000377855 / NM_181864.3; = p.L150= on NM_007274.4) | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV64113151; called by muse, mutect2, varscan2
- ANK1 | c.4212G>A p.E1404= | Silent (SNP) | VAF 68/130 reads (52%) | catalogued as COSV55880099; called by muse, mutect2, varscan2
- BRCA2 | c.3387G>A p.Q1129= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV66452875; called by muse, mutect2, varscan2
- CACNA2D3 | c.426C>T p.D142= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as rs532127932, COSV55533510; called by muse, mutect2, varscan2
- CCDC191 | c.2559G>A p.K853= | Silent (SNP) | VAF 303/522 reads (58%) | catalogued as COSV55671748; called by muse, mutect2, varscan2
- CDHR2 | c.183G>T p.G61= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as COSV56138008; called by muse, mutect2, varscan2
- CDYL | c.159C>T p.S53= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs781104414, COSV61039669; called by muse, mutect2, varscan2
- CLCN6 | c.1215G>A p.S405= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs374880026; called by muse, mutect2, varscan2
- CNTN6 | c.2856T>C p.I952= | Silent (SNP) | VAF 66/98 reads (67%) | catalogued as COSV63170447; called by muse, varscan2
- COL5A2 | c.4470C>T p.G1490= | Silent (SNP) | VAF 71/199 reads (36%) | catalogued as rs142895373; ClinVar: likely benign; called by muse, mutect2, varscan2
- DSCAM | c.1788G>A p.P596= | Silent (SNP) | VAF 90/99 reads (91%) | catalogued as rs200014864; ClinVar: likely benign; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.549G>A p.V183= | Silent (SNP) | VAF 46/764 reads (6%) | called by muse, mutect2
- FBXW10 | c.705C>T p.S235= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs746970458, COSV100111498, COSV57316613; called by muse, mutect2, varscan2
- FCRL2 | c.1059C>A p.S353= | Silent (SNP) | VAF 207/1300 reads (16%) | catalogued as COSV63833406; called by muse, mutect2, varscan2
- FRMD4B | c.1287A>G p.E429= | Silent (SNP) | VAF 81/148 reads (55%) | catalogued as COSV68329738; called by muse, mutect2, varscan2
- GFAP | c.1326C>A p.G442= (on ENST00000253408 / NM_001363846.2; = p.G402= on NM_002055.5) | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV53650329; called by muse, mutect2, varscan2
- HAUS7 | c.342C>T p.H114= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as rs368562448, COSV57848660; called by muse, mutect2, varscan2
- IBSP | c.813C>T p.Y271= | Silent (SNP) | VAF 95/236 reads (40%) | catalogued as rs1304341987, COSV56895135; called by muse, mutect2, varscan2
- LDLRAD3 | c.750G>A p.A250= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs140347483, COSV100215313; called by muse, mutect2, varscan2
- MACF1 | c.15237G>A p.Q5079= (on ENST00000372915; = p.Q3012= on NM_012090.5) | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV57118917, COSV57123021; called by muse, mutect2
- MATN4 | c.546C>T p.R182= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59213492; called by muse, mutect2, varscan2
- MED23 | c.1098T>C p.I366= | Silent (SNP) | VAF 73/311 reads (23%) | catalogued as rs1234767574, COSV63432232; called by muse, mutect2, varscan2
- METTL16 | c.1608T>C p.V536= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV54013468; called by muse, mutect2, varscan2
- MRAS | c.435G>A p.A145= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs754375420, COSV56670688; called by muse, mutect2, varscan2
- PATE1 | c.36G>T p.L12= | Silent (SNP) | VAF 100/355 reads (28%) | catalogued as COSV59824404; called by muse, mutect2, varscan2
- PDE5A | c.489G>A p.L163= | Silent (SNP) | VAF 245/406 reads (60%) | catalogued as rs1420849578, COSV53347799; called by muse, mutect2, varscan2
- PRKCH | c.1653C>T p.H551= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs758220032, COSV60647862; called by muse, mutect2, varscan2
- PRKN | c.990G>T p.V330= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PTPN14 | c.2763G>A p.A921= | Silent (SNP) | VAF 69/217 reads (32%) | catalogued as rs146527644, COSV65283594; called by muse, mutect2, varscan2
- SLC18A2 | c.753G>A p.P251= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs926621814, COSV53690253; called by muse, mutect2, varscan2
- SOHLH2 | c.561T>G p.L187= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV100499587; called by muse, mutect2
- TAF1L | c.3918G>T p.V1306= | Silent (SNP) | VAF 191/572 reads (33%) | catalogued as COSV54261261; called by muse, mutect2, varscan2
- TCF21 | c.345C>T p.L115= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs761923325; called by muse, mutect2, varscan2
- UBAP2 | c.423C>T p.G141= | Silent (SNP) | VAF 128/409 reads (31%) | catalogued as rs140158168, COSV100670873, COSV62546477; called by muse, mutect2, varscan2
- ZNF34 | c.186C>T p.D62= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs759237384, COSV58639277; called by muse, mutect2
- ZNF699 | c.1086T>C p.P362= | Silent (SNP) | VAF 38/212 reads (18%) | called by muse, varscan2
- MIR521-2 | n.16C>A | RNA (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- SF3B3 | c.826-292A>T | Intron (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
